Gene-level copy-number profile of tumor specimen C3N-01752-02 from CPTAC case C3N-01752, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 73.2 years (26,753 days).
Specimen C3N-01752-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fe0d9a75-cd05-4ff2-b0c6-6535941ffcec.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01752-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/f972b4f2-3ce6-487e-bf68-eb5d55857768

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 620; copy number 1: 10,291; copy number 2: 39,273; copy number 3: 6,711; copy number 4: 834; copy number 5: 1,044; copy number 6: 25; copy number 7: 74; copy number 8: 24; copy number 11: 15.

Homozygous deletions (total copy number 0; autosomes only): 106 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:21,160,235–22,214,672, 49 genes: Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:23,690,104–27,944,497, 38 genes: ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1.
- chr9:63,581,254–64,082,534, 15 genes: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP, AL163540.1, U6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,182 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–40,798,374, 601 genes, copy number 5–8 (broad region; genes not listed).
- chr5:107,376,889–109,499,108, 22 genes, copy number 5: EFNA5, AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17, AC133134.1, LINC01023, FER, AC034207.1, AC008871.1, Y_RNA, AC109481.1, RNU6-47P, GJA1P1, AC116428.1, AC008467.1, PJA2, AC010625.1, AC091917.3, AC091917.2, AC091917.1.
- chr11:10,797,050–15,930,951, 83 genes, copy number 5–8 (broad region; genes not listed).
- chr11:101,451,564–101,872,562, 1 gene, copy number 5 (within-gene range 3–5): TRPC6.
- chr11:101,765,935–107,963,482, 101 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–18,650,966, 17 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr18:316,737–4,455,307, 88 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr18:22,699,481–23,026,488, 8 genes, copy number 5: AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr18:25,818,234–26,099,226, 4 genes, copy number 5: RN7SL97P, AC027229.1, SS18, RPS24P18.
- chr21:8,603,547–8,603,984, 1 gene, copy number 8: RPSAP68.
- chr22:24,011,192–31,530,634, 254 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr22:31,490,150–31,521,592, 2 genes, copy number 5 (within-gene range 4–5): AL096701.4, H2AZP6.

Autosomal genes at a single copy (total copy number 1): 7,949. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
